Gene-level copy-number profile of tumor specimen TCGA-DX-A8BV-01A from TCGA case TCGA-DX-A8BV, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Fibromyxosarcoma; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 57.5 years (21,005 days).
Specimen TCGA-DX-A8BV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.7e814757-fd09-40c3-8743-473904052f7f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DX-A8BV-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a26b78c9-532b-428f-8a9a-d2f482f6fd96

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 65; copy number 1: 1,240; copy number 2: 10,180; copy number 3: 17,630; copy number 4: 23,124; copy number 5: 5,007; copy number 6: 1,304; copy number 7: 337; copy number 8: 55; copy number 9: 138; copy number 11: 121; copy number 12: 612.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DX-A8BV-01A-11D-A37B-01): tumor purity 0.51, ploidy 3.45, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 65 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:48,232,612–51,080,862, 65 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 871 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–45,895,970, 710 genes, copy number 9–12 (broad region; genes not listed).
- chr13:105,410,816–114,337,626, 161 genes, copy number 9–11 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 657. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
